Surgical pathology report (de-identified scan), TCGA case TCGA-CN-4729, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-CN-4729-01A (Primary Tumor).

[page 1 of 5]
PATIENT HISTORY:

CHIEF COMPLAINT/ PRE-OP/ POST-OP DIAGNOSIS: This is a [REDACTED] with no history given.

PROCEDURE: Left composite resection, left neck dissection.

SPECIFIC CLINICAL QUESTION: Not answered.

OUTSIDE TISSUE DIAGNOSIS: Not answered.

PRIOR MALIGNANCY: Not answered.

CHEMORADIATION THERAPY: Not answered.

ORGAN TRANSPLANT: Not answered.

IMMUNOSUPPRESSION: Not answered.

OTHER DISEASES: Not answered.

[REDACTED]

FINAL DIAGNOSIS:

PART 1: LEFT NECK, LEVEL 1, DISSECTION –

- A. SEVEN BENIGN LYMPH NODES, (0/7).
- B. SUBMANDIBULAR GLAND WITH NO SPECIFIC PATHOLOGIC CHANGE.

PART 2: LEFT NECK, LEVELS 2-3, DISSECTION –

METASTATIC SQUAMOUS CELL CARCINOMA IN ONE OF SEVENTEEN LYMPH NODES (1/17), (EXTRA-NODAL EXTENSION IS SEEN) .

PART 3: RETRO-MOLAR TRIGONE, LEFT, COMPOSITE RESECTION –

- A. INVASIVE SQUAMOUS CELL CARCINOMA, WELL-TO-MODERATELY DIFFERENTIATED, 2.4 CM.
- B. TUMOR EXTENDS TO THE PERIOSTEAL SURFACE OF MANDIBLE, BUT DOES NOT INVADE THE BONE DIRECTLY.
- C. BONE , MUCOSAL AND SOFT TISSUE MARGINS OF RESECTION ARE FREE OF TUMOR (SEE PARTS 4-8).
- D. NO PERINEURAL INVASION IS SEEN.
- E. MANDIBLE SHOWS INTRA-OSSEOUS FIBROSIS AND REACTIVE CHANGES.
- F. PATHOLOGIC STAGE: pT2 N1 Mx.

PART 4: LEFT LINGUAL NERVE, EXCISION –
NO TUMOR SEEN.

PART 5: BUCCAL MARGIN, EXCISION –
NO TUMOR SEEN.

PART 6: SOFT PALATE MARGIN, EXCISION –
NO TUMOR SEEN.

PART 7: HARD PALATE MARGIN, EXCISION –
NO TUMOR SEEN.

[page 2 of 5]
Pathology Report

PART 8: TONGUE MARGIN, EXCISION –
NO TUMOR SEEN.

COMMENT:

Immunohistochemical staining for p16 will be performed on part 3, the results of which will be reported in an addendum.

My signature is attestation that I have personally reviewed the submitted material(s) and the final diagnosis reflects that evaluation.

GROSS DESCRIPTION:

The specimen is received fresh in eight parts each labeled with the patient's name, medical record number and initials .

Part 1 is received labeled "left neck level I." It consists of a submandibular gland with surrounding fibro-lymphatic tissue having an overall measurement of 6.5 x 5.0 x 2.3 cm. The submandibular gland measure 3.7 x 3.0 x 1.5 cm. It is surrounded by abundant brown-yellow adipose tissue that contains numerous firm, tan-white lymph nodes ranging in size from 0.4 to 1.1 cm in diameter. The submandibular gland has a smooth lobular contour and on cross section is uniformly firm and white in appearance.

Representative sections are submitted for permanent histology as follows:

- 1A – three lymph nodes
- 1B – three lymph nodes
- 1C-1D – level 1 adipose
- 1E – submandibular gland.

Part 2 is received labeled "left neck levels II and III." It consists of a single large piece of fibroadipose tissue having an overall measurement of 5.8 x 5.5 x 3.0 cm. Scattered throughout the tissue are numerous firm, tan lymph nodes measuring from 0.3 to 0.1 cm in diameter. Representative sections are submitted for permanent histology as follows:

- 2A-2B – lymph nodes
- 2C-2E – levels II and III adipose.

Part 3 is received labeled "left composite resection." It consists of a left angle of mandible with attached oral soft tissue having an overall measurement of 7.5 x 5.3 x 3.5 cm. The body of the mandible measures 4.5 cm from the angle and the ramus measures 3.0 cm from the angle. Immediately medial to the angle is a 2.4 x 1.5 cm firm, white fungating mass lesion involving the mucosal surface. Cross-sections through the lesions show it to abut the neighboring mandible in more than one area with no obvious direct bone involvement. Following tissue banking, and digital imaging, representative sections are submitted for histology as follows:

- 3A – body margin
- 3B – ramus margin
- 3C – tumor adjacent to mandible
- 3D-3F – representative sections of tumor.

Part 4 is received labeled "left lingual nerve." It consists of a single piece of soft, tan tissue measuring 0.5 x 0.3 x 0.2 cm. Following an intraoperative frozen section, the entire tissue is submitted for permanent histology in a cassette labeled 4AFS.

Part 5 is received labeled "buccal margin, clip inferior, true margin inked." It consists of two pieces of soft, tan tissue collectively measuring 1.8 x 1.5 x 0.4 cm. Following an intraoperative frozen section, the entire tissue is submitted for permanent histology in a single cassette labeled 5AFS.

[page 3 of 5]
Pathology Report

Part 6 is received labeled "soft palate margin, clip inferior." It consists of a single piece of soft, tan tissue measuring 2.0 x 0.4 x 0.3 cm. following an intraoperative frozen section, the entire tissue is submitted for permanent histology in a cassette labeled 6AFS.

Part 7 is received labeled "hard palate margin, clip medial, inked true margin." It consists of a single piece of soft, tan and white tissue measuring 3.1 x 0.3 x 0.3 cm. Following an intraoperative frozen section, the entire tissue is submitted for permanent histology in a single cassette labeled 7AFS.

Part 8 is received labeled "tongue margin, clip anterior, true margin inked." It consists of a single piece of soft, tan tissue measuring 2.0 x 1.3 x 0.4 cm. Following an intraoperative frozen section, the entire tissue is submitted for permanent histology in a single cassette labeled 8AFS.

INTRAOPERATIVE CONSULTATION:

PART 4AFS: LEFT LINGUAL NERVE (frozen section) –

- A. BENIGN.
- B. NO TUMOR

PART 5AFS: BUCCAL MARGIN (frozen section) –

- A. BENIGN.
- B. NO TUMOR

PART 6AFS: SOFT PALATE (frozen section) –

- A. BENIGN.
- B. NO TUMOR

PART 7AFS: HARD PALATE (frozen section) –

- A. BENIGN.
- B. NO TUMOR

PART 8AFS: TONGUE (frozen section) –

- A. BENIGN.
- B. NO TUMOR

MICROSCOPIC:

Microscopic examination substantiates the above diagnosis.

The following statement applies to all immunohistochemistry, insitu hybridization (ISH & FISH), molecular anatomic pathology, and immunofluorescence testing:

The testing was developed and its performance characteristics determined by the Department of Pathology, as required by the regulations. The testing has not been cleared or approved for the specific use by the U.S. Food and Drug Administration, but the FDA has determined such approval is not necessary for clinical use. Tissue fixation ranges from a minimum of 2 to a maximum of 84 hours.

This laboratory is certified under the Clinical Laboratory Improvement Amendments of ("CLIA") as qualified to perform high-complexity clinical testing. Pursuant to the requirements of CLIA, ASR's used in this laboratory have been established and verified for accuracy and precision. Additional information about this type of test is available upon request.

[page 4 of 5]
Pathology Report

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY UPPER AERODIGESTIVE TRACT AND SALIVARY GLAND TUMORS

SPECIMEN TYPE: Resection: composite
TUMOR SITE: Oral Cavity
TUMOR SIZE: Greatest dimension: 2.4 cm
HISTOLOGIC TYPE: Squamous cell carcinoma, conventional
HISTOLOGIC GRADE: G2
PATHOLOGIC STAGING (pTNM): pT2
pN1
Number of regional lymph nodes examined: 24
Number of regional lymph nodes involved: 1
pMX
MARGINS: Margins uninvolved by tumor
Distance of tumor from closest margin: 5 mm
VENOUS/LYMPHATIC (LARGE/SMALL VESSEL) INVASION (V/L):
Present
PERINEURAL INVASION: Absent
ADDITIONAL PATHOLOGIC FINDINGS: None identified

HISTO TISSUE SUMMARY/SLIDES REVIEWED:

Part 1: Left Neck Level I

Stain/cnt	Block
H&E x 1	A
H&E x 1	B
H&E x 1	C
H&E x 1	D
H&E x 1	E

Part 2: Left Neck Level II and III

Stain/cnt	Block
H&E x 1	A
H&E x 1	B
H&E x 1	C
H&E x 1	D
H&E x 1	E

Part 3: Left Composite Resection

Stain/cnt	Block
H&E x 1	D
H&E x 1	E
H&E x 1	F
Decal x 1	Adr
H&E x 1	Adr
Decal x 1	Bdr
H&E x 1	Bdr
Decal x 1	Cdr
H&E x 1	Cdr

[page 5 of 5]
Pathology Report

Part 4: Left Lingual Nerve

Stain/cnt Block
H&E x 1 Afs

Part 5: Buccal Margin, Clip Inferior True Margin Inked

Stain/cnt Block
H&E x 1 Afs

Part 6: Soft Palate Margin, Clip Inferior

Stain/cnt Block
H&E x 1 Afs

Part 7: Hard Palate Margin, Clip Medial Inked True Margin

Stain/cnt Block
H&E x 1 Afs

Part 8: Tongue Margin, Clip Anterior True Margin Inked

Stain/cnt Block
H&E x 1 Afs

ICD-9 Diagnosis Codes: {None Entered}

Source: NCI Genomic Data Commons file 0e9cbda3-da2e-461e-8fd6-5bd1eed74166 (TCGA-CN-4729.2EAE3920-18BF-4EDD-85AB-FDB817CA04BE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).